Somatic mutation profile of tumor specimen 0DSW9W from CCDI case PBCBCB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,768 days).
Specimen 0DSW9W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3020bd90-cf09-48f4-ac2c-88d73cabfcb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSW9F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0f4e953-a6e1-48da-91f6-20e5c865ccc0

The open-access MAF lists 29 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 7, Silent 5, 3'UTR 2, Splice Site 2, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5438A>G p.E1813G | Missense Mutation (SNP) | VAF 286/342 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, varscan2
- ARHGEF10L | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs1414327313; called by muse, varscan2
- ARHGEF10L | c.818A>G p.H273R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as rs1408594257, COSV51437671; called by muse, varscan2
- FGFR2 | c.562A>G p.T188A | Missense Mutation (SNP) | VAF 150/272 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.147); catalogued as rs1352732939; called by muse, varscan2
- LZTR1 | c.1843_1845del p.K615del | In Frame Del (DEL) | VAF 14/105 reads (13%) | catalogued as rs746246349; called by pindel, varscan2
- DNAH5 | c.1644+4G>T | Splice Region (SNP) | VAF 94/332 reads (28%) | called by muse, varscan2
- GLO1 | c.467-1G>T p.X156_splice | Splice Site (SNP) | VAF 30/236 reads (13%) | called by muse, varscan2
- GLO1 | c.467-2A>C p.X156_splice | Splice Site (SNP) | VAF 30/232 reads (13%) | called by muse, varscan2
- HMGCLL1 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 176/318 reads (55%) | called by muse, varscan2
- NF1 | c.3672_3676dup p.A1226Gfs*16 | Frame Shift Ins (INS) | VAF 101/148 reads (68%) | called by pindel, varscan2
- NRAP | c.1843G>C p.V615L (on ENST00000359988 / NM_001322945.2; = p.V580L on NM_006175.4) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0.115); called by muse, varscan2
- NRF1 | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, varscan2
- PTPRD | c.3506T>A p.L1169Q | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, varscan2
- TENM1 | c.2149G>T p.V717L | Missense Mutation (SNP) | VAF 57/256 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, varscan2
- ACSM5 | c.1134C>T p.I378= | Silent (SNP) | VAF 50/120 reads (42%) | called by muse, varscan2
- CHRM5 | c.483C>G p.L161= | Silent (SNP) | VAF 77/144 reads (53%) | called by muse, varscan2
- OR6C2 | c.801C>G p.A267= | Silent (SNP) | VAF 222/378 reads (59%) | called by muse, varscan2
- SBF2 | c.3774A>T p.P1258= | Silent (SNP) | VAF 74/185 reads (40%) | called by muse, varscan2
- SNX19 | c.162G>T p.L54= | Silent (SNP) | VAF 52/121 reads (43%) | called by muse, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 32/299 reads (11%) | called by muse, varscan2
- EIF3I | c.251-18G>T | Intron (SNP) | VAF 20/112 reads (18%) | called by muse, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 8/79 reads (10%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, varscan2
- GMPR2 | c.208-69G>A | Intron (SNP) | VAF 16/55 reads (29%) | called by muse, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- MYCBPAP | c.-8G>C | 5'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, varscan2
- RAB11A | c.*100C>A | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, varscan2
- TMEM135 | c.462+78C>G | Intron (SNP) | VAF 29/112 reads (26%) | called by muse, varscan2
- UBE2L3 | c.27+61G>A | Intron (SNP) | VAF 12/56 reads (21%) | called by muse, varscan2
